Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3352, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3352-01A (Primary Tumor).

[page 1 of 3]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

SEE REPORT

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

A. LEFT KIDNEY, [REDACTED]

==== PRE-OPERATIVE DIAGNOSIS: =====

Left renal mass

==== POST-OPERATIVE DIAGNOSIS: =====

None provided

==== CLINICAL INFORMATION: =====

None provided

==== INTRAOPERATIVE CONSULTATION: =====

APC DIAGNOSIS: "Some tumor obtained for cancer genomics study" by [REDACTED]

==== GROSS DESCRIPTION: =====

[REDACTED] Received in formalin is a kidney with attached perirenal adipose tissue and adrenal glands. The specimen weighs 1,204 grams and measures 24.0 x 15.0 x 7.0 cm in overall dimensions. The kidney measures 11.0 cm from superior to inferior, 8.5 cm from medial to lateral, and 4.5 cm from anterior to posterior. The kidney weighs 350 grams. Located at the hilum is a 1.3 cm in length x 0.4 cm in diameter portion of artery which is adjacent to a portion of renal vein which is bifurcated and measures 2.0 cm in length x 0.3 cm in diameter. The ureter measures 10.0 cm in length x 0.2 cm in diameter. The external surface consists of a large amount of bosselated tan-yellow perirenal adipose tissue. On sectioning, a fairly well circumscribed mass is identified within the lower pole which measures 5.5 x 4.0 x 4.0 cm in overall dimension. The cut surface consists of soft, diffusely congested, red golden yellow tissue with scattered irregular, gray-tan, cystic areas. The solid tissue comprises approximately 60% of the cut surface and the cystic portion 40%. The lesion lies subjacent to the renal pelvis and shows possible focal extension into the adjacent hilar fat. This focal extension is located adjacent to a portion of the renal artery. The mass involves 50% of the lower pole and also shows irregular satellite lesions composed of soft golden yellow-red tissue which range in size from 0.2 to 0.8 cm in greatest dimension. The mass is located 4.0 cm from the renal artery/renal vein margin. The mass measures 1.0 cm from the radial soft tissue margin. The capsule surrounding the mass strips with ease. The remainder of the renal parenchyma is pink-brown with a distinct corticomedullary junction. The cortex measures 0.5 cm in thickness and the medulla measures 1.2 cm in thickness. The cortical surface is pink-tan, smooth and glistening. The

[page 2 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Requested by: [REDACTED]

:Surgical Report

ureter is lined by longitudinally folded pink-tan mucosa. The pelvic mucosa is pink-tan, smooth and glistening. The renal vein is purple-pink, smooth, glistening, and does not appear involved by the lesion. The renal artery is yellow-tan and focally calcified. On sectioning through the hilum, a 0.8 cm possible pink-tan lymph node is identified. The adrenal gland measures approximately 2.5 x 1.0 x 1.0 cm. On sectioning, the cut surface consists of golden yellow parenchyma. Sectioning is otherwise unremarkable. Representative sections are submitted in eleven cassettes as follows: cassette 1 - vascular and ureteral margin; cassette 2 - mass with overlying pelvic mucosa; cassettes 3 through 5 - mass, with possible extension into pelvic fat in cassette 3; cassettes 6 and 7 - satellite lesions; cassettes 8 and 9 - upper and lower pole uninvolved; cassette 10 - adrenal gland; cassette 11 - additional adrenal gland and possible lymph node.

===== MICROSCOPIC DESCRIPTION: =====

[REDACTED] The tumor consists of cells with abundant clear cytoplasm. Nuclei are moderately large with very irregular contours. Some have a moderately coarse chromatin pattern with prominent nucleoli. The tumor has a lobulated pattern and is present multifocally. Some areas of tumor necrosis are present. Tumor extends into the peripelvic fat of the renal sinus. Extensive involvement of large veins is present. Areas of prominent calcification and thickening of renal artery are present. No involvement of vessels from the hilar margin is seen. The parenchyma adjacent to some of the tumor has extensive numbers of globally sclerotic glomeruli with chronic inflammation. The grossly described satellite lesions consist of tumor within veins. No lymph node is present. The adrenal gland is normal in appearance. The other tissue with adrenal, in slide 11, consists of abundant ganglion cells. The renal parenchyma away from tumor shows little pathologic change. Some areas with globally sclerotic glomeruli are present however most glomeruli are within normal limits. In addition, there are some areas of interstitial fibrosis and there is some arterial wall thickening.

===== FINAL DIAGNOSIS: =====

A/APC. LEFT KIDNEY, NEPHRECTOMY:

1. CLEAR CELL RENAL CARCINOMA
2. HISTOLOGIC GRADE: G3
3. PATHOLOGIC STAGING: pT3a (MAXIMUM TUMOR SIZE OF 5.5 CM WITH EXTENSION INTO RENAL SINUS FAT)
4. REGIONAL LYMPH NODES: pNX
5. DISTANT METASTASIS: pMX
6. MARGINS: UNINVOLVED BY INVASIVE CARCINOMA
7. ADRENAL GLAND: UNINVOLVED BY TUMOR

[page 3 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

:Surgical Report

-
8. VENOUS (LARGE VESSEL) INVASION: EXTENSIVELY PRESENT
9. SMALL VESSEL INVASION: NOT SEEN
10. ADDITIONAL FINDINGS:
- PRESENCE OF GANGLIA

A-MALIGNANT

[REDACTED]
(Electronic Signature)

DATE AND TIME OF REPORT: [REDACTED]

Source: NCI Genomic Data Commons file 35e670ba-4b21-4047-a78b-fbcaa01d00e0 (TCGA-A3-3352.70A93356-089B-4552-95AB-5BE14E49102C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).